Gene-level copy-number profile of tumor specimen TCGA-AC-A5EH-01A from TCGA case TCGA-AC-A5EH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.6 years (27,964 days).
Specimen TCGA-AC-A5EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.cbcffc05-aa0d-493e-a5e3-47bbb833af4c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A5EH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7045d14-82cc-428d-adc0-acea6fb2b52f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 14,841; copy number 2: 42,288; copy number 3: 1,936; copy number 4: 142; copy number 5: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A5EH-01A-11D-A28A-01): tumor purity 0.42, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 324 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,839–54,295,272, 1 gene (within-gene range 0–1): AC058822.1.
- chr4:53,659,208–58,565,212, 96 genes (within-gene range 0–1) (broad region; genes not listed).
- chr4:69,387,580–70,085,290, 22 genes: AC114786.4, UGT2B25P, AC108078.1, UGT2B24P, AC108078.3, AC108078.2, UGT2B4, UGT2A3P7, AC093829.1, UGT2A2, UGT2A1, SULT1B1, SULT1D1P, AC108941.3, SULT1E1, AC108941.1, CSN1S1, CSN2, STATH, HTN3, HTN1, CSN1S2AP.
- chr9:3,181,342–3,526,004, 3 genes (within-gene range 0–1): LINC01231, RFX3, AL354941.1.
- chr9:19,957,394–30,990,572, 138 genes (broad region; genes not listed).
- chr17:11,598,470–12,768,949, 15 genes: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1.
- chr17:14,834,557–15,999,717, 49 genes: LINC02096, RPL23AP76, AC005772.1, CDRT7, AC005772.2, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:35,068,211–35,912,516, 75 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,029. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
